TCGA case TCGA-FP-A8CX — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Stomach; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/feb5ccf3-395f-415a-85d3-db637fcd514f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (2)
1. Signet ring cell carcinoma (the primary disease): ICD-O-3 morphology code: 8490/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 60.2 years (22,000 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N3a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 7 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 15; Lymph nodes tested: 25.
2. Seminoma, NOS: ICD-O-3 morphology code: 9061/3; Tissue or organ of origin: Testis, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 7 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD; Reflux treatment type: Proton Pump Inhibitors; Risk factors: GERD.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FP-A8CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 40 mg.
  Slide TCGA-FP-A8CX-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-FP-A8CX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FP-A8CX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach Adenocarcinoma, Signet Ring Type; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Tumor sample procurement country: Texas; Cancer procurement city: Tyler; History reflux disease indicator: Yes; Antireflux treatment: Yes; History barretts esophageal indicator: No; History hpylori infection indicator: No; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Testicle; Other malignancy histological type: Seminoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Tumor Resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 7 days; disease-specific survival: no event (censored), 7 days; progression-free interval: no event (censored), 7 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FP-A8CX-01A-11D-A363-01): tumor purity 0.27, ploidy 3.1, whole-genome doublings 1.
